Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-B1HR, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-B1HR-TTP1-A (Primary Tumor).

[page 1 of 13]
Surgical Pathology Report

Patient Name: [REDACTED] Accession No: [REDACTED]
Date of Procedure: [REDACTED] +0 Date Received: [REDACTED] +0
Sex: Female Date of Birth: [REDACTED]
Referring Physician: [REDACTED] Service: [REDACTED]
Hospital No: [REDACTED]

Addendum Report [REDACTED] +15 +2

This addendum supercedes the original report issued [REDACTED] This report includes results of 1p,19q and EGFR analysis performed at [REDACTED] The diagnosis remains unchanged. The comment below is added.

Clinical History:

The patient is a [REDACTED] female with a left frontal lesion. Recent right side facial weakness and right upper extremity weakness and difficulty with speech.

Microscopic Diagnosis:

Brain lesion, left frontal lobe (x3), craniotomy:
- Glioblastoma multiforme, WHO grade IV

Addendum Comment [REDACTED] +15

Interphase Molecular Cytogenetic (FISH) Studies:

Negative for deletion of 1p36 sequences (ratio 1p36:1q25=1.00)
Negative for deletion of 19q13 sequences (ratio 19q13:19p13=0.96)
No evidence of amplification of EGFR (7p12) sequences
Polysomy for #1, #7 and #19 observed

Gross Description:

Specimen #1, received fresh for frozen section, labeled with the patient's name and hospital number and designated "left frontal tumor", are numerous fragments of pink soft gelatinous tissue measuring 2 x 0.6 x 0.3 cm in aggregate. A representative section is submitted for frozen section diagnosis and subsequently submitted in cassette (FS-1). The remainder of the specimen is submitted entirely in cassette (A).

Received later in formalin are two additional specimens.

Specimen #2, designated "left frontal tumor", are multiple fragments of white-tan soft tissue measuring 2.5 x 2 x 1.0 cm in aggregate. Serial sectioning reveals a homogenous white-tan cut surface without gross abnormality. Representative sections are submitted in cassettes (B-D).

Specimen #3, designated "L frontal lesion [REDACTED]", is a synthetic closed sac measuring 25 cm in length and 4.5 cm in average width. Opening of the bag reveals multiple small fragments of white-tan soft tissue measuring 3 x 3 x .5 cm in aggregate. The specimen is submitted entirely in cassettes (E-G). Gross description performed by [REDACTED]

Frozen Section Diagnosis:

[page 2 of 13]
Surgical Pathology Report

Patient Name: [Redacted]
Date of Procedure: [Redacted] +0
Sex: Female
Referring Physician: [Redacted]

Accession No: [Redacted]
Date Received: [Redacted] +0
Date of Birth: [Redacted]
Service: [Redacted]
Hospital No: [Redacted]

(FS-1) Brain lesion, left frontal lobe, craniotomy: glioma with prominent gemistocytic features

The following special procedures were performed on this case:

- ^MIB-1 +
- ^p53 +
- *GFAP +

Note: The above list of special procedures does not reflect test results. Please refer to Microscopic Description or Diagnosis, for the interpretation of the results of special stains.

Microscopic Description:

The diagnosis of glioblastoma multiforme is formulated base on the presence of hypercellularity, frequent mitoses, vascular proliferation and focal necrosis. There are prominent gemistocytic tumor cells in the lesion.

11/11/11

[page 3 of 13]
Surgical Pathology Report

Patient Name:

Date of Procedure:

Sex:

Referring Physician:

Female

+0

Accession No:

Date Received:

Date of Birth:

Service:

+0

Hospital No:

The following Stains were performed on this specimen. Please reference the Microscopic Description for each specimen.

Stain	Block
^MIB-1 +	B
^p53 +	B
*GFAP +	B

The following cases, on this patient, were collected on the same day as this case.

[page 5 of 13]
[REDACTED]

MR BRAIN W&W/O

Exam Date: [REDACTED] +407 [REDACTED]

decrease in T2 signal abnormality deep and inferior to the resection bed.

Interpreting Radiologist: [REDACTED]

[REDACTED]

[REDACTED]

[page 6 of 13]
MR BRAIN W&W/O

Exam Date: [REDACTED] +609

Dept: [REDACTED]

Pt. Status: D

Patient Loc:

Requesting MD: [REDACTED]

MR BRAIN W&W/O CONTRAST

ACC# [REDACTED] EXAM DATE: [REDACTED] +609

Diagnosis: GRD 4 ASTRO LEFT FRONTAL INSULAR
History: ASSESS FOR INTERVAL CHANGE

MRI BRAIN WITH AND WITHOUT CONTRAST on [REDACTED] +609

HISTORY: Grade 4 left frontal astrocytoma. Assess for change.

TECHNIQUE: Axial T1-weighted images. Axial T2-TSE, T2-FLAIR and T2-GRE images. Sagittal, axial and coronal post contrast T1-weighted images.

COMPARISON: [REDACTED] +505

FINDINGS: There is extensive frontal metal artifact, likely from braces.

Appearance of left frontal postoperative cavity with surrounding increased T2 signal, is unchanged. The blood products at the resection margins. No new lesions are seen. There is resolution of prior seen small extra-axial collection at the craniotomy site. Ventricles are symmetrical without midline shift.

IMPRESSION:

No significant change in left frontal surgical bed with stable surrounding T2 signal. No new lesions.

[Continued On Next Page]

[page 7 of 13]
MR BRAIN W&W/O

Exam Date:

+609

[REDACTED]

[REDACTED]

[page 8 of 13]
MR BRAIN W&W/O

Exam Date: [REDACTED] +1

Dept: [REDACTED]

Pt. Status: D

Patient Loc:

Requesting MD: [REDACTED]

MR BRAIN W&W/O CONTRAST

ACC: [REDACTED] EXAM DATE: [REDACTED] +1

Diagnosis: LT FRONTAL TUMOR

History: S/P RESECTION

DATE OF DICTATION: [REDACTED] +1

INDICATIONS: Left frontal lobe tumor status post resection.

TECHNIQUE: Precontrast axial T1-weighted, T2-TSE, T2-FLAIR, T2-GE images. Post contrast sagittal, axial and coronal images.

+0

FINDINGS: Since the MRI done [REDACTED] this patient has undergone a left frontal craniotomy. The enhancing lesion in the left frontal lobe has been resected. High T1 signal in the surgical bed is consistent with blood products. No definite enhancement is identified, though this is difficult to assess, due to adjacent blood. Postoperative pneumocephalus is present. A 7 mm left frontal subdural hematoma is present. Increased T2 signal extending inferiorly from the surgical site to the operculum has not changed.

IMPRESSION:

1. Status post resection of left frontal lobe tumor. No definite enhancing lesion is identified, but peripheral enhancement of residual tumor could be obscured by blood products in the operative bed.

2. Unchanged vasogenic edema, extending inferiorly from the base of

[Continued On Next Page]

[page 9 of 13]
[REDACTED]

MR BRAIN W&W/O

Exam Date: [REDACTED] +1 [REDACTED]

the operative site to the left operculum.

3. Small left frontal subdural hematoma.

*2A

[REDACTED]

[REDACTED]

[page 10 of 13]
MR BRAIN W CON

Exam Date: [REDACTED] +0

Dept: [REDACTED]

PT. Status: D

Patient Loc:

Requesting MD: [REDACTED]

MR BRAIN WITH CONTRAST

ACC# [REDACTED] EXAM DATE: [REDACTED] +0

Diagnosis: BRAIN TUMOR FRONTAL LOBE 191.1

History: PRE-OP EVAL. STRYKER NAVIGATION T1 AND T2 WITH GAD

DATE OF DICTATION: [REDACTED] +2

INDICATIONS: Left frontal lobe brain tumor. Striker navigation preop evaluation.

TECHNIQUE: 3 mm axial postcontrast T1, T2 images. 3 mm coronal postcontrast T1 images. 5 mm sagittal postcontrast T1 images.

FINDINGS: A 3.2 x 2.7 x 3.8cm presumably enhancing mass (no precontrast images are available) is present in the left frontal lobe, within the inferior frontal gyrus, extending inferiorly to the operculum. Surrounding high T2 signal is present, primarily inferior to the lesion. Mild mass effect with indentation of the left lateral ventricle is present. No other enhancing lesions are identified. Fiducial markers are in position.

IMPRESSION:

Images satisfactory for preoperative planning. Presumably enhancing left frontal lobe mass with surrounding vasogenic edema as above.

*1A

[Continued On Next Page]

[page 11 of 13]
[REDACTED]

[REDACTED]

MR BRAIN W CON

Exam Date: [REDACTED] +0

[REDACTED]

[REDACTED]

[REDACTED]

[page 12 of 13]
RADIOLOGY REPORT

Patient Information

Age/Sex: [REDACTED] Female

Birth Date: [REDACTED]

Signs & Symptoms: left frontal/insular grade 4 astrocytoma completed [REDACTED] surveillance study
History: Glioblastoma (HC code)

Order Information

Exam(s): **MR BRAIN W/VO CONTRAST** [REDACTED]

Accession # [REDACTED]

Exam Date: [REDACTED] +3976

Ord Provider: [REDACTED]

Final

MRI BRAIN WITHOUT AND WITH CONTRAST - [REDACTED] +3976

HISTORY: left frontal/insular grade 4 astrocytoma completed [REDACTED]; surveillance study. Assess for interval change. +407

TECHNIQUE: 5 mm axial T2-weighted FLAIR, T2-weighted, precontrast T1-weighted, and post contrast T1-weighted images were performed through the brain. 5 mm axial diffusion-weighted images with apparent diffusion coefficient maps were also performed through the brain. 1 mm parasagittal postcontrast 3D T1-weighted images were performed through the brain. Axial, coronal and parasagittal reformatted images were created from the thin T1-weighted images. 2.4 mm susceptibility weighted images were obtained through the brain and thick MinIP images were created. Arterial spin labelled perfusion imaging was obtained through the brain.

The patient received an intravenous injection of 20 ml of Multihance with no adverse reaction.

FINDINGS: Comparison is made to MRI of the brain from [REDACTED]. +3640
+3640

Brain and intracranial structures: Since [REDACTED], there has been no significant change in the left frontal lobe resection cavity with surrounding T2/FLAIR hyperintensity. Surrounding susceptibility is again noted, likely indicating blood products. There are no areas in or around the resection cavity which demonstrates increased perfusion on ASL or contrast enhancement.

Small focus of CSF signal within the left peritrial white matter is stable in size measuring up to 1 cm (series 8 image 16). Incidental developmental venous anomaly within the right midbrain is unchanged.

There is no mass lesion, hemorrhage or acute infarct.

[page 13 of 13]
Skull: Stable post operative changes of left frontal/temporal and parietal craniotomy.

Scalp: Postoperative changes overlying the craniectomy site.

Orbits and face (included portions): Slightly hypoplastic right maxillary sinus is again noted.

Paranasal sinuses and mastoid air cells (included portions): Normal.

IMPRESSION:

1. Stable postoperative changes within the left frontal lobe without evidence of residual or recurrent tumor.
2. Unchanged 1 cm cystic area within the left peritrial white matter likely reflects an enlarged perivascular space.

If you are a health care provider and have any questions regarding this or any other neuroradiology report please call: [REDACTED] The neuroradiology reading area location is [REDACTED] We are staffed 8 am to 5 pm, Monday through Friday.

If you are a patient and have questions about your report please contact your health care provider.

[REDACTED]

Reading Physician: [REDACTED]

Reviewed and Interpreted By: [REDACTED] +3976

Source: NCI Genomic Data Commons file 64a518cc-1e7d-4a57-81ce-a117220b9e30 (ER0394 ER-B1HR Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).